Somatic mutation profile of tumor specimen C3N-02265-01 (aliquot CPT0188900006) from CPTAC case C3N-02265, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 55.7 years (20,336 days).
Specimen C3N-02265-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65182269-a0cb-495f-ad07-d9a8d67d5ed3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02265-31 (Blood Derived Normal), aliquot CPT0188940002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02204dcb-74d3-4dbb-bea0-9f17602f2881

The open-access MAF lists 88 somatic variants for this specimen: 61 protein-altering or splice-affecting, 13 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 13, Frame Shift Del 9, Intron 6, Nonsense Mutation 3, Splice Site 2, 5'UTR 2, RNA 2, 5'Flank 2, Frame Shift Ins 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLUL | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 75/387 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); catalogued as rs80358215, CM057403, COSV59381541; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PRKAR1A | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 94/423 reads (22%) | catalogued as rs886041228, CM093288; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VHL | c.292_295del p.Y98Qfs*60 | Frame Shift Del (DEL) | VAF 118/521 reads (23%) | catalogued as rs1559426095; ClinVar: pathogenic; called by pindel, varscan2
- ACSBG2 | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 32/540 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs771329990; called by muse, mutect2
- BRPF3 | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 64/411 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as rs767000902, COSV60207340; called by muse, mutect2, varscan2
- CELF4 | c.719G>T p.R240L | Missense Mutation (SNP) | VAF 112/654 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV58445248; called by muse, mutect2, varscan2
- CYBB | c.1702G>C p.E568Q | Missense Mutation (SNP) | VAF 54/372 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM011933; called by muse, mutect2, varscan2
- DENND4A | c.4327A>G p.M1443V | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.041); catalogued as rs763584548; called by muse, mutect2, varscan2
- GRIA1 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 81/407 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.081); catalogued as COSV53621996; called by muse, mutect2, varscan2
- ITIH5 | c.2027C>T p.T676I | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756723555; called by muse, mutect2, varscan2
- KLHL36 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 89/430 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs764581089, COSV99256987; called by muse, mutect2, varscan2
- LIFR | c.3231_3232del p.P1078* | Frame Shift Del (DEL) | VAF 30/178 reads (17%) | catalogued as rs776513402; called by pindel, varscan2
- PTPRR | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 118/611 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.317); catalogued as rs370625173; called by muse, mutect2, varscan2
- SLC47A1 | c.920T>G p.M307R | Missense Mutation (SNP) | VAF 52/287 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54503056; called by muse, mutect2, varscan2
- SYNRG | c.253A>G p.M85V | Missense Mutation (SNP) | VAF 61/272 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.036); catalogued as rs756505295; called by muse, mutect2, varscan2
- TRPM5 | c.2284C>T p.Q762* | Nonsense Mutation (SNP) | VAF 56/210 reads (27%) | catalogued as rs927289304; called by muse, mutect2, varscan2
- ZBTB20 | c.1838G>T p.R613L (on ENST00000474710 / NM_001164342.2; = p.R540L on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100614671; called by muse, mutect2
- ZNF746 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 62/387 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs766494668, COSV61406835; called by muse, mutect2, varscan2
- ABCA1 | c.2265C>A p.F755L | Missense Mutation (SNP) | VAF 123/640 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ACSM5 | c.1727A>G p.E576G | Missense Mutation (SNP) | VAF 55/246 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACY3 | c.237-2A>G p.X79_splice | Splice Site (SNP) | VAF 28/91 reads (31%) | called by muse, mutect2
- AIM2 | c.705G>C p.K235N | Missense Mutation (SNP) | VAF 55/294 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- CEMIP | c.3712A>C p.K1238Q | Missense Mutation (SNP) | VAF 101/536 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- CPD | c.3601A>C p.K1201Q | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- CXXC1 | c.1582C>T p.R528* | Nonsense Mutation (SNP) | VAF 53/190 reads (28%) | called by muse, mutect2, varscan2
- CYP3A43 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- FAM13C | c.1054G>T p.G352W | Missense Mutation (SNP) | VAF 91/359 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- FMO4 | c.1187_1188del p.C396* | Frame Shift Del (DEL) | VAF 45/270 reads (17%) | called by mutect2, pindel, varscan2
- GRHL2 | c.467C>T p.T156M | Missense Mutation (SNP) | VAF 108/525 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GRIA1 | c.1289A>T p.E430V | Missense Mutation (SNP) | VAF 82/411 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- HSF5 | c.296G>C p.G99A | Missense Mutation (SNP) | VAF 202/821 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IMP4 | c.307_309del p.X103_splice | Splice Site (DEL) | VAF 36/222 reads (16%) | called by mutect2, pindel, varscan2
- IP6K2 | c.253_294del p.I85_I98del | In Frame Del (DEL) | VAF 38/328 reads (12%) | called by mutect2, pindel
- KDR | c.3796T>A p.S1266T | Missense Mutation (SNP) | VAF 28/359 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2
- KIF20B | c.4190C>G p.A1397G (on ENST00000371728 / NM_001284259.2; = p.A1357G on NM_016195.4) | Missense Mutation (SNP) | VAF 56/319 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- KLF3 | c.281_288del p.G94Dfs*82 | Frame Shift Del (DEL) | VAF 89/370 reads (24%) | called by mutect2, pindel, varscan2
- KLHL38 | c.472G>C p.V158L | Missense Mutation (SNP) | VAF 65/380 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MCM8 | c.1807C>T p.H603Y | Missense Mutation (SNP) | VAF 48/269 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- NRBP1 | c.1179C>A p.F393L | Missense Mutation (SNP) | VAF 9/237 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.411); called by muse, mutect2
- OPLAH | c.1267T>A p.S423T | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PARP6 | c.1497T>A p.H499Q | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PRKAG3 | c.799C>T p.H267Y | Missense Mutation (SNP) | VAF 60/316 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RGS17 | c.193del p.Q65Rfs*3 | Frame Shift Del (DEL) | VAF 24/174 reads (14%) | called by mutect2, pindel, varscan2
- SLX4IP | c.1113G>C p.M371I | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- SPATA18 | c.1466G>C p.R489T | Missense Mutation (SNP) | VAF 95/493 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPEF1 | c.650_653delinsTTT p.K217Ifs*73 | Frame Shift Del (DEL) | VAF 33/189 reads (17%) | called by pindel, varscan2*
- STARD9 | c.3358C>G p.L1120V | Missense Mutation (SNP) | VAF 86/444 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- SWT1 | c.2026A>C p.S676R | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- TMC2 | c.2339A>C p.K780T | Missense Mutation (SNP) | VAF 56/268 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TMEM200B | c.765dup p.E256* | Frame Shift Ins (INS) | VAF 49/277 reads (18%) | called by mutect2, pindel, varscan2
- TMPRSS11B | c.106G>C p.V36L | Missense Mutation (SNP) | VAF 47/227 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- TRRAP | c.4293del p.M1432* | Frame Shift Del (DEL) | VAF 40/256 reads (16%) | called by mutect2, pindel, varscan2
- TSHZ2 | c.2380G>T p.D794Y | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TSPAN6 | c.179del p.V60Afs*31 | Frame Shift Del (DEL) | VAF 15/91 reads (16%) | called by mutect2, pindel, varscan2
- VAV3 | c.686C>G p.A229G | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- WRAP53 | c.935G>A p.C312Y | Missense Mutation (SNP) | VAF 68/353 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.52); called by muse, varscan2
- ZBTB21 | c.1604G>A p.G535D | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- ZMYND15 | c.1576G>T p.V526L (on ENST00000433935 / NM_001136046.3; = p.V487L on NM_032265.2) | Missense Mutation (SNP) | VAF 58/249 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- ZNF287 | c.2103G>T p.E701D | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF608 | c.315A>T p.K105N | Missense Mutation (SNP) | VAF 92/472 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZSWIM8 | c.3760_3761del p.G1254Qfs*84 (on ENST00000605216 / NM_001242487.2; = p.G1259Qfs*84 on NM_015037.3) | Frame Shift Del (DEL) | VAF 77/476 reads (16%) | called by mutect2, pindel, varscan2
- AFF4 | c.972G>A p.T324= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as rs939378259, COSV54797178; called by muse, mutect2
- ARRDC3 | c.810T>A p.I270= | Silent (SNP) | VAF 60/316 reads (19%) | catalogued as rs1179469661; called by muse, mutect2, varscan2
- EEA1 | c.3684A>G p.G1228= | Silent (SNP) | VAF 44/201 reads (22%) | called by muse, mutect2
- FBXO24 | c.645C>A p.T215= (on ENST00000241071 / NM_033506.3; = p.T253= on NM_012172.5) | Silent (SNP) | VAF 100/521 reads (19%) | called by muse, mutect2, varscan2
- IL17A | c.399C>T p.F133= | Silent (SNP) | VAF 71/370 reads (19%) | catalogued as COSV60684405; called by muse, mutect2, varscan2
- LRRC10B | c.450G>T p.A150= | Silent (SNP) | VAF 59/234 reads (25%) | catalogued as rs901766284; called by muse, mutect2, varscan2
- OR51C1P | c.198G>C p.L66= | Silent (SNP) | VAF 22/77 reads (29%) | called by muse, mutect2, varscan2
- PKN1 | c.858G>A p.R286= | Silent (SNP) | VAF 56/199 reads (28%) | called by muse, mutect2, varscan2
- PPP2R3C | c.1101T>C p.N367= | Silent (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- TCP11X2 | c.774G>A p.P258= | Silent (SNP) | VAF 113/1056 reads (11%) | called by muse, mutect2, varscan2
- TLE1 | c.2139T>C p.F713= | Silent (SNP) | VAF 21/122 reads (17%) | called by muse, mutect2, varscan2
- UNC45A | c.1905G>T p.R635= | Silent (SNP) | VAF 36/156 reads (23%) | called by muse, mutect2, varscan2
- VPS36 | c.810C>T p.Y270= | Silent (SNP) | VAF 45/264 reads (17%) | called by muse, mutect2, varscan2
- AC009053.1 | n.771C>G | RNA (SNP) | VAF 60/452 reads (13%) | called by muse, mutect2, varscan2
- CCDC73 | c.429+55T>G | Intron (SNP) | VAF 20/103 reads (19%) | called by muse, mutect2, varscan2
- HMBS | c.826-33A>T | Intron (SNP) | VAF 149/622 reads (24%) | called by muse, mutect2, varscan2
- IGSF9B | chr11:133956759 C>A | 5'Flank (SNP) | VAF 34/242 reads (14%) | called by muse, mutect2, varscan2
- LTBP3 | c.662-72C>G | Intron (SNP) | VAF 36/149 reads (24%) | called by muse, mutect2, varscan2
- MED14 | chrX:40735704 C>A | 5'Flank (SNP) | VAF 131/453 reads (29%) | called by muse, mutect2, varscan2
- MIR1208 | n.32G>C | RNA (SNP) | VAF 49/245 reads (20%) | called by muse, mutect2, varscan2
- PALLD | c.-45C>A | 5'UTR (SNP) | VAF 40/166 reads (24%) | called by muse, mutect2, varscan2
- SLC26A4 | c.164+30A>T | Intron (SNP) | VAF 59/210 reads (28%) | called by muse, mutect2, varscan2
- SLC29A3 | c.-48G>A | 5'UTR (SNP) | VAF 48/174 reads (28%) | called by muse, mutect2, varscan2
- SULF1 | c.*159G>T | 3'UTR (SNP) | VAF 66/267 reads (25%) | called by muse, mutect2, varscan2
- TNPO2 | c.1496+53G>C | Intron (SNP) | VAF 84/356 reads (24%) | called by muse, mutect2, varscan2
- TTN | c.34265-5081G>A | Intron (SNP) | VAF 68/375 reads (18%) | catalogued as rs750296116; called by muse, mutect2, varscan2
- Unknown | chr10:972804 C>T | IGR (SNP) | VAF 66/350 reads (19%) | called by muse, mutect2, varscan2
